Gene-level copy-number profile of tumor specimen ALCH-B2UH-TTP1-A from ALCHEMIST case ALCH-B2UH, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 54.2 years (19,781 days).
Specimen ALCH-B2UH-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 5fbb7cc9-f8c3-41f5-aec1-a3c75fb1228a.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B2UH-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,222 have no estimate.
https://portal.gdc.cancer.gov/files/020f9995-4daa-4a14-9eae-5e411b0cb621

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 7; copy number 1: 2,538; copy number 2: 53,729; copy number 3: 2,110; copy number 4: 6; copy number 7: 11.

Homozygous deletions (total copy number 0; autosomes only): 7 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:1,530,702–1,560,821, 2 genes: MAFK, TMEM184A.
- chr22:18,773,665–18,843,399, 3 genes: GGT3P, AC008132.2, E2F6P1.
- chr22:23,510,154–23,513,602, 2 genes: AP000345.3, LINC02557.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 11 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr17:22,406,019–22,530,609, 11 genes, copy number 7: FLJ36000, AC132825.3, AC132825.4, MTCYBP13, MTRNR2L1, AC132825.2, MTND1P15, MTND2P13, AC132825.1, NMTRS-TGA3-1, MTATP6P3.

Autosomal genes at a single copy (total copy number 1): 1,749. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
